Gene-level copy-number profile of tumor specimen TCGA-WZ-A7V5-01A from TCGA case TCGA-WZ-A7V5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 27.1 years (9,886 days).
Specimen TCGA-WZ-A7V5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.fece4b57-ec7a-499e-8ac7-9d46649ab3e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WZ-A7V5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9628be61-9536-455c-b2c1-ca5892931276

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 364; copy number 2: 24,715; copy number 3: 24,411; copy number 4: 6,478; copy number 5: 2,803; copy number 6: 285; copy number 7: 561; copy number 8: 203.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WZ-A7V5-01A-11D-A434-01): tumor purity 0.38, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 764 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:51,541,144–71,583,989, 289 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:71,289,769–71,305,853, 1 gene, copy number 7: FOXP1-AS1.
- chr3:106,449,775–109,723,273, 60 genes, copy number 7 (within-gene range 2–7): LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445.
- chr12:11,132,958–23,251,499, 211 genes, copy number 7 (broad region; genes not listed).
- chr12:46,183,063–51,037,602, 203 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
